Surgical pathology report (de-identified scan), TCGA case TCGA-06-0882, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0882-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

06-0882

CLINICAL HISTORY

developed left sided headache after head injury on [REDACTED]
On imaging, in the left medial frontal lobe there is a 5.9 cm.,
ring-enhancing mass with hemorrhage, extensive edema, and extension to the
genu of the corpus callosum. There is past history of [REDACTED]

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Left frontal tumor, biopsy
B: Frontal tumor
C: Marginal tissue superior gyrus

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, left frontal, excisional biopsy and excision:

1. Gliosarcoma.
2. MIB-1 proliferation index: 18%.

C. Brain, marginal tissue superior gyrus, excision: Glioma, infiltrative,
focal, small.

See Microscopy Description and Comment.

COMMENT

In parts A and B there is a neoplastic glial proliferation that diffusely
infiltrates and extensively effaces cerebral tissue, and has nuclear
anaplasia, frequent mitoses, prominent microvascular cellular proliferation
with vascular necrosis and thrombosis, and extensive areas of necrosis, some
with pseudopalisading. In part B there is also a large zone that has a
spindle cell configuration with nuclear anaplastic features.
The neoplasm is a glioblastoma with focal sarcomatoid phenotype, i.e. a
gliosarcoma.

Part B is cerebral cortex and adjacent white matter in which there is one
microscopic focal area that is sparsely infiltrated by naked neoplastic cells.

[page 2 of 4]
PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Test performed on paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] Laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

INTRA-OPERATIVE CONSULTATION

A.

Left frontal tumor, biopsy: Atypical glial proliferation consistent with high-grade glioma. Frozen section and smear preparations performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A.

Received fresh from the operating room, labeled with the patient's name and MRN, are several fragments of soft tan tissue, approximately 1.5 x 1.2 x 0.4 cm in aggregate. Samples are used for frozen sections and smears. The frozen residual is submitted in A1 and the unfrozen tissue is submitted in A2.

B.

SPECIMEN: Frontal tumor.

FIXATIVE: Formalin.

GENERAL: Received is a 5.5 x 3.5 x 1.5 cm. aggregate of irregular, gray-white to dusky red-brown soft to rubbery focally hemorrhagic tissue fragments. Sectioning reveals fleshy gray-white focally hemorrhagic cut surfaces.

SECTIONS: Representative sections in three cassettes B1-B3.

C.

SPECIMEN: Marginal tissue superior gyrus.

[page 3 of 4]
FIXATIVE: Formalin.

GENERAL: Received is a 2 x 1.5 x 1 cm. fragment of brain tissue. One aspect is cauterized and ragged and the opposite is pink-tan glistening with arborizing vessels. Specimen is sectioned to reveal pink-tan to gray-white cut surfaces.

SECTIONS: C1,C2 entirely submitted.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: In part A, the GFAP demonstrates heavy gliofibrillogenesis by the neoplastic cells, including some ganglion-like cells. In part B, the GFAP depicts extensive spindle cell areas that are negative and intermingled with GFAP-positive strands. Only a small minority (about 5%) of cells over expresses the p53 protein. The CD163 marks a large number of cells, presumably phagocytic. With the MIB-1 there is a proliferation index of about 18% in the more active areas.

SPECIAL STAIN: The Snook's reticulum demonstrates heavy reticulin deposition in the spindle, GFAP-negative areas.

The stains results are consistent with a high histological grade glial neoplasm that has a sarcomatoid component.

ICD-9(s):

239.6 239.6

Histo Data

Part A: Left frontal tumor, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
FS H/E x 1		1		
H/E x 1		1		
TPS H/E x 1		1		
H/E x 1		2		
H/E x 1		3		

Part B: Frontal tumor

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
CD163 Vector x 1		1		
mGFAP-DA x 1		1		
H/E x 1		1		
MGMT x 1		1		
MIB1-DA x 1		1		
NeuN x 1		1		
P53DO7 x 1		1		
H/E x 1		2		
mGFAP-DA x 1		3		
H/E x 1		3		
Retic x 1		3		

Part C: Marginal tissue superior gyrus

Taken: Received:

[page 4 of 4]
[REDACTED]

Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file d265b2b4-c668-40c9-8044-8545b8db448d (TCGA-06-0882.F2DE8883-BC9A-4578-A154-A70335786740.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).